Somatic mutation profile of tumor specimen 1105256 (aliquot 7316UP-3639-1105256) from CPTAC case C1245129, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105256: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c783e1-988d-439f-b3bf-f3bc4915c7bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105282 (Blood Derived Normal), aliquot 7316UP-2923-1105282; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6efe689-3544-43df-9035-16223734f4ca

The open-access MAF lists 66 somatic variants for this specimen: 51 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Frame Shift Del 7, Silent 6, 3'UTR 3, RNA 2, Intron 2, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 176/399 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55960968; called by muse, mutect2, varscan2
- BIN3 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs73671219; called by muse, mutect2, varscan2
- BLK | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV52056465; called by muse, mutect2, varscan2
- CD1A | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs140989108, COSV56860759; called by muse, mutect2, varscan2
- CDH18 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs565236156, COSV56907812, COSV99932062; called by muse, mutect2, varscan2
- DOCK8 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs1227911560, COSV66634653; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HHLA1 | c.1295C>A p.P432Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs1368020543; called by muse, mutect2, varscan2
- KIF14 | c.2461A>G p.K821E | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100950850; called by muse, mutect2, varscan2
- LARP1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 98/414 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs757070815, COSV60430890; called by muse, mutect2, varscan2
- LSR | c.1375del p.E459Sfs*137 (on ENST00000361790; = p.E440Sfs*137 on NM_015925.6) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV99723286; called by mutect2, varscan2
- MYO1G | c.2457G>C p.M819I | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.222); catalogued as rs767722811, COSV99348404; called by muse, mutect2, varscan2
- NF1 | c.6645A>G p.A2215= (on ENST00000358273 / NM_001042492.3; = p.A2194= on NM_000267.3) | Splice Region (SNP) | VAF 42/274 reads (15%) | catalogued as CD076853; called by muse, mutect2, varscan2
- PCDHGA6 | c.1922G>A p.S641N | Missense Mutation (SNP) | VAF 108/495 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.044); catalogued as rs1265900699, COSV53948522; called by muse, mutect2, varscan2
- PROKR1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs769294148; called by muse, mutect2, varscan2
- PTEN | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV64291337, COSV64303263; called by muse, mutect2, varscan2
- SAMD3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1188118842, COSV60774329; called by muse, mutect2, varscan2
- SUSD2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750589882; called by muse, mutect2, varscan2
- TRPC7 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV61465068; called by muse, mutect2, varscan2
- VPS33B | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.287); catalogued as COSV60979239; called by muse, mutect2, varscan2
- ACAP2 | c.1521_1526del p.Y507_E509delins* | Nonsense Mutation (DEL) | VAF 30/156 reads (19%) | called by mutect2, pindel
- ARHGEF9 | c.1465T>A p.S489T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS10 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- BPTF | c.2618A>T p.K873M | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAGE1 | c.2263T>A p.L755I (on ENST00000512086; = p.L619I on NM_205864.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CFAP54 | c.2804G>C p.W935S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ECM2 | c.378C>G p.C126W | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FASTKD3 | c.333_339del p.S112Kfs*3 | Frame Shift Del (DEL) | VAF 38/162 reads (23%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.2325A>T p.E775D | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLCCI1 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GPR22 | c.974G>T p.C325F | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GZF1 | c.180del p.F60Lfs*20 | Frame Shift Del (DEL) | VAF 39/157 reads (25%) | called by mutect2, pindel, varscan2
- KCNQ3 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LIN52 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- LRRC37A3 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 142/814 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- MKI67 | c.4849T>C p.S1617P | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMP12 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF3 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH11X | c.1061C>A p.S354Y | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PIWIL1 | c.879T>G p.H293Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHA8 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- POLH | c.1135del p.S379Afs*17 | Frame Shift Del (DEL) | VAF 66/311 reads (21%) | called by mutect2, pindel, varscan2
- RB1 | c.1881del p.N627Kfs*16 | Frame Shift Del (DEL) | VAF 36/165 reads (22%) | called by mutect2, pindel, varscan2
- SNX13 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2
- SPIN3 | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TACC2 | c.3875C>G p.A1292G | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD6 | c.3350A>T p.E1117V | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- TTC3 | c.134_144+6del p.X45_splice | Splice Site (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel
- ZFHX2 | c.5175del p.E1726Nfs*19 | Frame Shift Del (DEL) | VAF 55/299 reads (18%) | called by mutect2, pindel, varscan2
- ZNF234 | c.1603del p.S535Vfs*47 | Frame Shift Del (DEL) | VAF 58/280 reads (21%) | called by mutect2, pindel, varscan2
- ZNF671 | c.1499T>C p.V500A | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ADAMTS20 | c.1770C>T p.N590= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs763702051, COSV67127794; called by muse, mutect2, varscan2
- BRSK1 | c.945G>T p.L315= | Silent (SNP) | VAF 48/239 reads (20%) | catalogued as COSV58667667; called by muse, mutect2, varscan2
- KCNA5 | c.642C>T p.R214= | Silent (SNP) | VAF 97/521 reads (19%) | catalogued as COSV99364284; called by muse, mutect2, varscan2
- PCDHAC2 | c.147A>G p.P49= | Silent (SNP) | VAF 62/331 reads (19%) | called by muse, mutect2, varscan2
- PLCH1 | c.4629C>T p.T1543= (on ENST00000340059 / NM_001130960.2; = p.T1535= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/334 reads (22%) | catalogued as rs374800898, COSV58185384; called by muse, mutect2, varscan2
- SUSD3 | c.537C>T p.H179= | Silent (SNP) | VAF 71/249 reads (29%) | catalogued as rs556738504; called by muse, mutect2, varscan2
- AC010507.1 | chr19:200423 A>G | 3'Flank (SNP) | VAF 16/189 reads (8%) | called by muse, varscan2
- ADAM21P1 | n.1140C>T | RNA (SNP) | VAF 66/344 reads (19%) | catalogued as rs755338109; called by muse, mutect2, varscan2
- AHSA2P | n.1588C>T | RNA (SNP) | VAF 47/227 reads (21%) | called by muse, mutect2, varscan2
- ALAS2 | c.*28C>A | 3'UTR (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- CBX8 | chr17:79798266 G>A | 5'Flank (SNP) | VAF 16/85 reads (19%) | catalogued as rs763144138; called by muse, mutect2, varscan2
- CTDSPL | c.*1734G>A | 3'UTR (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- NGDN | c.72+17C>G | Intron (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- POLD4 | c.*10T>A | 3'UTR (SNP) | VAF 16/94 reads (17%) | catalogued as rs1244054357; called by muse, mutect2, varscan2
- RTEL1 | c.958+23C>T | Intron (SNP) | VAF 48/220 reads (22%) | called by muse, mutect2
